Somatic mutation profile of tumor specimen TCGA-RD-A8MW-01A (aliquot TCGA-RD-A8MW-01A-11D-A364-08) from TCGA case TCGA-RD-A8MW, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 72.8 years (26,590 days).
Specimen TCGA-RD-A8MW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29e18efa-e88a-47b7-bce0-efd12829efde.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RD-A8MW-10A (Blood Derived Normal), aliquot TCGA-RD-A8MW-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6598566-d20c-4ab4-a90d-b09db51630f5

The open-access MAF lists 83 somatic variants for this specimen: 57 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 24, Frame Shift Del 5, Frame Shift Ins 2, Splice Site 1, Intron 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.812T>A p.V271D | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV100253392; called by muse, mutect2, varscan2
- ABLIM1 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs200441310, COSV99522866; called by muse, mutect2
- ACADSB | c.608G>C p.G203A | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100715348; called by mutect2, varscan2
- ADAMTS18 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.041); catalogued as rs758362638, COSV51422374; called by muse, mutect2, varscan2
- ALMS1 | c.8245dup p.V2749Gfs*3 | Frame Shift Ins (INS) | VAF 38/155 reads (25%) | catalogued as rs748621056; called by mutect2, pindel, varscan2
- ASCC3 | c.3638A>C p.H1213P | Missense Mutation (SNP) | VAF 19/269 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100226466; called by muse, mutect2
- ASGR1 | c.670G>T p.V224L | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV99352634; called by muse, mutect2
- DCAF13 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as rs1243900525, COSV99885730; called by muse, mutect2, varscan2
- DNAH17 | c.5363G>A p.R1788Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371167564; called by muse, mutect2, varscan2
- DZIP1L | c.1067A>T p.Q356L | Missense Mutation (SNP) | VAF 63/85 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV100551798; called by muse, mutect2, varscan2
- FAM120A | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.167); catalogued as COSV99464278; called by muse, mutect2, varscan2
- FAT4 | c.6451A>C p.N2151H | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV100630507; called by muse, mutect2, varscan2
- FREM2 | c.1402T>G p.L468V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV54826828, COSV54842467; called by muse, mutect2
- FRY | c.3949G>C p.V1317L | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.053); catalogued as rs774866304, COSV100970026; called by muse, mutect2, varscan2
- KCTD15 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs376123855; called by muse, mutect2, varscan2
- KIT | c.656C>G p.A219G | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs1311536541, COSV55405755, COSV99855560; called by muse, mutect2, varscan2
- LRRC37A3 | c.4823G>A p.R1608Q | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs768967057, COSV58534675; called by muse, mutect2, varscan2
- LRRC6 | c.1123G>T p.V375F | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV99138768; called by muse, mutect2, varscan2
- LRRC7 | c.1746G>T p.L582F (on ENST00000651989 / NM_001370785.2; = p.L549F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1298638742, COSV99230408; called by muse, mutect2, varscan2
- LRRK2 | c.5302C>T p.P1768S | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100111377, COSV54172897; called by muse, mutect2
- MAP10 | c.2421_2427del p.I808Rfs*14 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | catalogued as rs754524812; called by mutect2, pindel, varscan2
- MAPRE3 | c.319T>A p.F107I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99252064; called by muse, mutect2, varscan2
- MID2 | c.1562G>A p.S521N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV99465814; called by muse, mutect2, varscan2
- MRPL16 | c.106G>C p.V36L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs1251770061, COSV100276551; called by muse, mutect2, varscan2
- NAV3 | c.5582A>G p.K1861R (on ENST00000397909 / NM_001024383.2; = p.K1839R on NM_014903.6) | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.993); catalogued as COSV99896569; called by muse, mutect2
- NPAT | c.1405G>C p.E469Q | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.698); catalogued as COSV99586430; called by muse, mutect2, varscan2
- NR3C1 | c.2077T>G p.Y693D | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99196887; called by muse, mutect2, varscan2
- OBSCN | c.11514G>T p.E3838D | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.91); catalogued as COSV52760530; called by muse, mutect2, varscan2
- PKD1L1 | c.5305G>A p.A1769T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs201316867, COSV99068873; called by muse, mutect2, varscan2
- PRKAA2 | c.1172A>G p.K391R | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100983114; called by muse, mutect2, varscan2
- PRTG | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1236608141, COSV101221515; called by muse, varscan2
- RAN | c.371T>C p.V124A | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV99619904; called by muse, mutect2, varscan2
- RASD1 | c.321C>A p.N107K | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV99245940; called by muse, mutect2, varscan2
- ROBO2 | c.2281G>A p.D761N | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV100170496, COSV59901818; called by muse, mutect2
- SALL4 | c.2375A>G p.N792S | Missense Mutation (SNP) | VAF 77/135 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as rs779778006, COSV99409942; called by muse, mutect2, varscan2
- SCG5 | c.406G>A p.D136N (on ENST00000300175 / NM_001144757.2; = p.D135N on NM_003020.4) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.752); catalogued as COSV100277025; called by muse, mutect2, varscan2
- SERPINB2 | c.676T>C p.S226P | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as COSV100208731; called by muse, mutect2
- SOX5 | c.1387G>C p.A463P | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100508559; called by muse, mutect2, varscan2
- SPDYE3 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 35/353 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as rs775869494, COSV60107937; called by muse, mutect2, varscan2
- SPICE1 | c.1864G>T p.V622F | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV99871917; called by muse, mutect2, varscan2
- TCF21 | c.292del p.A98Pfs*34 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | catalogued as COSV99399637; called by mutect2, varscan2
- TIMM44 | c.572A>G p.D191G | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99564397; called by muse, mutect2
- TMPRSS11F | c.77A>G p.D26G | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100678868; called by muse, mutect2, varscan2
- TTC19 | c.490A>T p.S164C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV99890484; called by muse, mutect2, varscan2
- VSIG4 | c.52T>A p.Y18N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV101038360; called by muse, varscan2
- ZBED4 | c.362G>A p.W121* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as COSV99351837; called by muse, mutect2, varscan2
- ZKSCAN1 | c.1247T>G p.L416R | Missense Mutation (SNP) | VAF 255/346 reads (74%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.731); catalogued as COSV100164396; called by muse, mutect2, varscan2
- ZNF217 | c.3053C>T p.S1018L | Missense Mutation (SNP) | VAF 43/556 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.541); catalogued as COSV100184968; called by muse, mutect2
- ZNF584 | c.1142C>G p.S381C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100183455; called by muse, mutect2, varscan2
- ZNF813 | c.1065C>G p.F355L | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV101125026; called by muse, mutect2, varscan2
- CARD8 | c.1555del p.R519Efs*111 (on ENST00000651546 / NM_001184900.3; = p.R469Efs*111 on NM_014959.5 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 43/159 reads (27%) | called by mutect2, pindel*, varscan2
- IGKV2D-24 | c.182T>G p.L61R | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.144); called by muse, mutect2
- MYCBP2 | c.9592del p.E3198Rfs*17 (on ENST00000357337; = p.E3236Rfs*17 on NM_015057.5) | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | called by mutect2, pindel, varscan2
- PLXNA4 | c.4706del p.D1569Afs*13 | Frame Shift Del (DEL) | VAF 10/116 reads (9%) | called by mutect2, pindel
- ROCK2 | c.1089_1099+37del p.X363_splice | Splice Site (DEL) | VAF 30/108 reads (28%) | called by mutect2, pindel
- ZNF628 | c.2342dup p.L782Sfs*104 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | called by mutect2, pindel
- ADRA2B | c.180G>T p.L60= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs1237152132, COSV101337395; called by muse, mutect2
- AFAP1L1 | c.1596C>T p.S532= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs556839333, COSV57049012; called by muse, mutect2
- ATP5MD | c.165G>T p.V55= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100428337, COSV100428342; called by muse, mutect2, varscan2
- C2orf49 | c.441G>A p.S147= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs1210336566, COSV99307680; called by muse, mutect2, varscan2
- CALB1 | c.120C>T p.I40= | Silent (SNP) | VAF 14/192 reads (7%) | catalogued as rs867587976, COSV99618564; called by muse, mutect2
- DST | c.16002C>G p.P5334= (on ENST00000361203 / NM_001374722.1; = p.P2922= on NM_015548.5) | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV99760825; called by muse, mutect2, varscan2
- EEF2K | c.672C>G p.P224= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99533786; called by mutect2, varscan2
- FLNC | c.5892C>T p.D1964= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs747546440, COSV57953370; ClinVar: benign; called by muse, mutect2, varscan2
- GRSF1 | c.528C>A p.R176= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99636119; called by muse, mutect2
- HAGH | c.787C>T p.L263= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV101272502; called by muse, mutect2, varscan2
- IGHM | c.255C>T p.H85= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as rs574185352; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1740T>G p.P580= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100151358; called by muse, mutect2, varscan2
- KCTD16 | c.1167C>A p.L389= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV101568911; called by muse, mutect2, varscan2
- LTBP1 | c.1698A>G p.S566= (on ENST00000404816 / NM_206943.4; = p.S240= on NM_000627.4) | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV100618049; called by muse, mutect2, varscan2
- MMP7 | c.525G>A p.T175= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs752373573, COSV52772500; called by muse, mutect2, varscan2
- NOL6 | c.3150G>A p.L1050= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99955307; called by muse, varscan2
- OR1L6 | c.540C>G p.L180= (on ENST00000373684; = p.L144= on NM_001004453.2) | Silent (SNP) | VAF 25/159 reads (16%) | catalogued as COSV100491026; called by muse, mutect2, varscan2
- OR4C15 | c.346T>C p.L116= (on ENST00000314644; = p.L62= on NM_001001920.2) | Silent (SNP) | VAF 22/148 reads (15%) | catalogued as COSV58952394, COSV58952408, COSV58954071; called by muse, mutect2, varscan2
- PCDHA7 | c.1974G>A p.S658= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV65336376; called by muse, mutect2, varscan2
- PCDHGA9 | c.405C>A p.A135= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV53946734, COSV99548870; called by muse, mutect2, varscan2
- POLR2C | c.717G>A p.L239= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV99538511; called by muse, mutect2, varscan2
- PRAMEF8 | c.1063T>C p.L355= | Silent (SNP) | VAF 20/105 reads (19%) | called by muse, mutect2, varscan2
- SYNE1 | c.17958C>T p.L5986= (on ENST00000367255 / NM_182961.4; = p.L5915= on NM_033071.3) | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV99583178; called by muse, mutect2
- TRAV13-2 | c.45G>A p.L15= | Silent (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- CTDSPL | c.426+1573A>G | Intron (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99829105; called by muse, mutect2
- LPAL2 | n.253G>A | RNA (SNP) | VAF 17/92 reads (18%) | catalogued as rs1230846529; called by muse, mutect2, varscan2
